MMRF case MMRF_2185 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/eaa26025-3680-4fb8-833d-22ed1a6bb5a0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.3 years (24,597 days); ISS stage: II; Days to last known disease status: 890 days (2.4 years); Days to last follow up: 890 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 165 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 183 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 219 days; Days to treatment end: 220 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 221 days; Days to treatment end: 221 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 533 days (1.5 years); Days to treatment end: 718 days (2.0 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 774 days (2.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1: M Protein 3.68 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 191 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1980 mg/dL; Immunoglobulin G 2.45 g/L; Immunoglobulin A 34.5 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 4.57 µg/mL; Lactate Dehydrogenase 1.73 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 8.08 ×10⁹/L; Absolute Neutrophil 4.54 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 24.3 mmol/L; Calcium 2.28 mmol/L; Albumin 34.1 g/L; Total Protein 8.8 g/dL; Glucose 6.27 mmol/L; C-Reactive Protein 0.33 mg/dL.
- Day 86 (ECOG 1): Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 5.41 ×10⁹/L; Absolute Neutrophil 2.33 ×10⁹/L; Platelets 336 ×10⁹/L; Creatinine 64.5 µmol/L; Calcium 2.3 mmol/L; Total Protein 6 g/dL; Glucose 8.25 mmol/L.
- Day 172: M Protein 0 g/dL; Immunoglobulin G 4.38 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 4.07 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.57 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 62.8 µmol/L; Calcium 2.3 mmol/L; Albumin 36.6 g/L; Total Protein 6.1 g/dL; Glucose 7.65 mmol/L.
- Day 249 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 7.51 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 3.79 ×10⁹/L; Absolute Neutrophil 2.56 ×10⁹/L; Platelets 18.7 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.35 mmol/L; Glucose 9.57 mmol/L.
- Day 347 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 9.63 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 1.78 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.06 ×10⁹/L; Absolute Neutrophil 2.05 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 73.4 µmol/L; Calcium 2.48 mmol/L; Albumin 43.5 g/L; Total Protein 6.9 g/dL; Glucose 9.02 mmol/L.
- Day 431 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 9.32 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.25 ×10⁹/L; Absolute Neutrophil 2.43 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 70.7 µmol/L; Calcium 2.43 mmol/L; Total Protein 6.7 g/dL; Glucose 10.2 mmol/L.
- Day 533 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.4 mg/dL; Immunoglobulin G 8.52 g/L; Immunoglobulin A 1.96 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 1.62 µg/mL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.69 ×10⁹/L; Absolute Neutrophil 2.44 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 75.1 µmol/L; Calcium 2.33 mmol/L; Albumin 41.5 g/L; Total Protein 6.9 g/dL; Glucose 9.19 mmol/L.
- Day 620 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 5.64 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.97 ×10⁹/L; Absolute Neutrophil 0.66 ×10⁹/L; Platelets 90.7 ×10⁹/L; Creatinine 78.7 µmol/L; Calcium 2.25 mmol/L; Albumin 38.2 g/L; Total Protein 7.2 g/dL; Glucose 7.81 mmol/L.
- Day 718 (ECOG 0): M Protein 0.56 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.7 mg/dL; Immunoglobulin G 9.52 g/L; Immunoglobulin A 8.36 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.52 µg/mL; Hemoglobin 7.13 mmol/L; Leukocytes 1.95 ×10⁹/L; Absolute Neutrophil 0.47 ×10⁹/L; Platelets 36.2 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Glucose 9.35 mmol/L.
- Day 802: M Protein 1.72 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.7 mg/dL; Immunoglobulin G 9.52 g/L; Immunoglobulin A 8.93 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.52 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 1.61 ×10⁹/L; Absolute Neutrophil 0.53 ×10⁹/L; Platelets 34.5 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 6.5 mmol/L; Calcium 2.25 mmol/L; Albumin 40.4 g/L; Total Protein 6.2 g/dL; Glucose 11.7 mmol/L.
- Day 890: M Protein 1.3 g/dL; Immunoglobulin G 3.84 g/L; Immunoglobulin A 15 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 3.73 µg/mL; Hemoglobin 5.82 mmol/L; Leukocytes 2.54 ×10⁹/L; Absolute Neutrophil 0.54 ×10⁹/L; Platelets 16.1 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 6.67 mmol/L; Calcium 2.38 mmol/L; Glucose 10 mmol/L.

Other clinical attributes
- Day 1: Weight: 82 kg; Height: 160 cm.

Biospecimens (2 samples)
- Sample MMRF_2185_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2185_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
